Surgical pathology report (de-identified scan), TCGA case TCGA-86-A456, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-A456-01A (Primary Tumor).

Procurement Date: Laterality: Tumor is composed of papillary glands, with elongated finger-like processes lined by moderately stratified cylindrical or cuboidal cells supported by fibrovascular connective tissue cores arranging back to back. Nuclei are irregular large, hyperchromatic with prominent nucleoli. Mitoses are present. Tumor invades in alveolar. The stroma is infiltration of inflammatory cells.

Path Report: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 1.5 x 2 x 2 cm

Histologic type: Papillary adenocarcinoma ✓

Histologic grade: Well differentiated

Tumor extent: Visceral pleura

Other tumor nodules: Not specified

Lymph nodes: 0/1 positive for metastasis (Mediastinal lymph node 0/1)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor invades in alveolar.

Comments: Left- upper ✓

ICD-O-3
adenocarcinoma, papillary, NOS
8260/3
Site: lung, upper lobe
8131/12 C34.1
RO

Reviewed/Initiated:	KMI	8/14/12

Source: NCI Genomic Data Commons file 825d472f-b871-40c7-9af1-d1275ac64483 (TCGA-86-A456.56606792-5083-4F1E-ABEF-711BACF546E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).